Gene-level copy-number profile of tumor specimen ALCH-AF1H-TTP1-A from ALCHEMIST case ALCH-AF1H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,192 days).
Specimen ALCH-AF1H-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4c96230d-a4eb-4aed-bb57-2d46af902f5b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF1H-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/59b3ab11-e248-46df-a555-daffec09be23

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 8,146; copy number 2: 30,649; copy number 3: 16,174; copy number 4: 2,769; copy number 5: 1,083; copy number 6: 1; copy number 9: 9; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,043,736–16,057,308, 1 gene: CLCNKB.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr10:131,772,398–131,833,508, 3 genes: LINC01164, AL450307.1, AL607033.1.
- chr11:77,102,840–77,215,241, 2 genes (within-gene range 0–1): OMP, MYO7A.
- chr13:113,748,511–113,751,089, 1 gene: LINC00552.
- chr15:20,826,454–21,058,440, 16 genes (within-gene range 0–9): AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B.
- chr15:21,080,812–21,081,447, 1 gene: BCAR1P2.
- chr15:21,250,180–21,260,147, 1 gene: NBEAP4.
- chr15:25,193,321–25,257,027, 33 genes (within-gene range 0–1): SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:75,674,322–75,712,848, 3 genes: CSPG4, AC105020.4, AC105020.1.
- chr16:68,310,974–68,448,508, 5 genes (within-gene range 0–1): PRMT7, AC020978.1, RNU4-30P, SMPD3, AC099521.2.
- chr16:70,661,204–70,686,053, 2 genes: MTSS2, AC020763.4.
- chr16:88,638,572–88,706,408, 7 genes: IL17C, CYBA, MVD, SNAI3-AS1, SNAI3, RNF166, AC138028.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,091 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes, copy number 9: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr5:58,198–314,974, 11 genes, copy number 5 (within-gene range 4–5): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6.
- chr5:288,833–290,321, 1 gene, copy number 5: AC021087.2.
- chr5:6,582,136–7,219,291, 12 genes, copy number 5: LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1.
- chr5:36,861,736–37,085,852, 4 genes, copy number 5: AC026741.1, NIPBL, KRT18P31, RPS4XP6.
- chr7:2,679,522–4,269,000, 14 genes, copy number 5: AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1, AC017000.1.
- chr7:6,952,625–10,239,863, 43 genes, copy number 5: AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3.
- chr7:10,451,311–10,476,878, 2 genes, copy number 5: HSPA8P8, AC009945.1.
- chr7:10,931,943–56,955,864, 760 genes, copy number 5 (broad region; genes not listed).
- chr7:57,119,614–62,275,678, 53 genes, copy number 5: ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, MTCO3P4, AC099654.7, MTND4P5, MTND5P7, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr8:98,943,595–104,589,024, 136 genes, copy number 5 (broad region; genes not listed).
- chr8:133,191,039–133,963,259, 19 genes, copy number 5: CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2.
- chr15:21,017,800–21,020,851, 2 genes, copy number 9: IGHD1OR15-1B, FAM30C.
- chr15:21,951,242–22,095,857, 7 genes, copy number 5–22 (within-gene range 2–22): MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,083,221, 1 gene, copy number 5 (within-gene range 3–5): OR4M2.
- chr15:32,394,365–32,536,926, 11 genes, copy number 5 (within-gene range 1–5): RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2.
- chr16:1,833,986–1,890,434, 4 genes, copy number 5 (within-gene range 3–5): MEIOB, AL031722.1, LINC00254, LINC02124.
- chr20:64,255,695–64,313,132, 4 genes, copy number 5: PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 7,510. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
